Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AAO9, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AAO9-01A (Primary Tumor).

[page 1 of 2]
Acct#:

Ord #=

SIGNED

Perform D/T=

SURGICAL PATH

(1 of 1)

Specimen Source: R TESTICLE CORD
CASE NO.:
GROSS EXAM DATE:
PHYSICIAN & PAGER #:

DIAGNOSIS (based on GROSS and MICROSCOPIC examination):

1. SEMINOMA (3 CM.), right testis and spermatic cord, procedure not stated. (See note)
2. LYMPHOVASCULAR INVASION NOT IDENTIFIED.
3. NO INVASION OF EPIDIDYMIS NOTED.
4. TUMOR LIMITED TO TESTIS.
5. MARGINS FREE OF TUMOR.
6. INTRATUBULAR GERM CELL NEOPLASIA.
7. PT1NXMX
8. TESTICULAR TISSUE WITH FOCAL TUBULAR ATROPHY AND EVIDENCE OF SPERMATOGENESIS.

GROSS DESCRIPTION:

The specimen is received unfixed labeled with the patient's name, and "right testis and spermatic cord." The specimen consists of a testis measuring 5.5 x 3.5 x 2.5 cm and weighing 42.4 grams. The spermatic cord measures 10.0 x 1.2 cm. The specimen is bivalved for tissue collection to go to Tissue Bank. Within the parenchyma of the testis, there is a tan, fleshy mass in one pole measuring 3.0 x 2.0 x 1.2 cm. The specimen capsule and spermatic cord are carefully inked in black. There is a rim of tan-colored normal appearing testis that measures 1.5 cm. The epididymis measures 3.5 x 1.0 cm. The cut surface is yellow-tan in color. The tumor mass is serially sectioned revealing a white-yellow core.

ICD-O-3

Seminoma NOS 9061/3
Site (R) Testis NOS C62.9
WS 8/31/14

[page 2 of 2]
Name:

Loc:

SURGICAL PATH

(Continued)

Acct#:

SUMMARY OF CASSETTES:

Cassettes 1 through 6 contain tumor and adjacent testis.

Cassette 7 contains tumor at and capsule.

Cassette 8 contains epididymis.

Cassette 9 contains the spermatic cord resection margin.

Cassette 10 contains the spermatic cord midway.

Cassette 11 contains the spermatic cord at the peritesticular area.

R11.

Dictated By:

Released By: -----

SIGNED

Transcribed:

Source: NCI Genomic Data Commons file 1f222ceb-fe15-44aa-b936-98b1c2e108a5 (TCGA-XE-AAO9-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).